Somatic mutation profile of tumor specimen MP2PRT-PAUADZ-TMP1-A (aliquot MP2PRT-PAUADZ-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUADZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,037 days).
Specimen MP2PRT-PAUADZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8712d5e-a632-4a62-b8e3-6dcc7255ea55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUADZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUADZ-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2f71351-58a2-410f-bfd9-33c77961da8d

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Intron 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.1340G>A p.R447Q (on ENST00000219054; = p.R368Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs145697504, COSV54586379; called by muse, mutect2, varscan2
- ACSM2B | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 48/590 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs146841908, COSV61658598; called by muse, mutect2
- ALG14 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773144547; called by muse, mutect2, varscan2
- CDH26 | c.1418T>C p.V473A | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs372909302; called by muse, mutect2
- COL6A3 | c.9352G>A p.E3118K | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.137); catalogued as rs755613566, COSV55082509; called by muse, mutect2, varscan2
- EPHX2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 46/404 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV66845833; called by muse, mutect2, varscan2
- FSCB | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.415); catalogued as rs1347933960; called by muse, mutect2
- HAS1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 30/473 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs781516429, COSV55787386; called by muse, mutect2
- NEBL | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767254277, COSV65839103; called by muse, mutect2, varscan2
- RBIS | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 39/249 reads (16%) | catalogued as rs1344228994; called by muse, mutect2, varscan2
- TCEAL5 | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 127/688 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV65503547; called by muse, mutect2, varscan2
- TTC12 | c.1704G>A p.M568I | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59097488; called by muse, mutect2
- TTN | c.35137G>A p.E11713K (on ENST00000591111; = p.E10786K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/381 reads (8%) | PolyPhen benign (0.003); catalogued as COSV100632276; called by muse, mutect2
- ZNF679 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 51/277 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV55379404; called by muse, mutect2, varscan2
- BMPER | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 36/520 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2
- FXR1 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2
- IGHV4-59 | c.350delinsTCCCCC | In Frame Ins (INS) | VAF 83/262 reads (32%) | called by pindel, varscan2*
- LRP2 | c.5805G>T p.W1935C | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MKI67 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MPO | c.1345A>T p.I449F | Missense Mutation (SNP) | VAF 18/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR8 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1CA | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 62/683 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2
- RBBP7 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 22/766 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2
- SLC18A1 | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SLC26A4 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLFN13 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SORCS1 | c.1967C>A p.S656Y | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- UBA2 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF836 | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 19/431 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATXN7L2 | c.63C>G p.L21= | Silent (SNP) | VAF 75/585 reads (13%) | catalogued as rs775952170, COSV63993623; called by muse, mutect2, varscan2
- CACNA1F | c.888G>A p.Q296= | Silent (SNP) | VAF 24/986 reads (2%) | catalogued as rs1361314345; called by muse, mutect2
- CXXC4 | c.87G>A p.L29= | Silent (SNP) | VAF 32/774 reads (4%) | called by muse, mutect2
- INTU | c.2094T>A p.G698= | Silent (SNP) | VAF 44/398 reads (11%) | called by muse, mutect2, varscan2
- TGM4 | c.198G>A p.P66= | Silent (SNP) | VAF 85/463 reads (18%) | catalogued as rs777957841, COSV56094891; called by muse, mutect2, varscan2
- TMEM92 | c.27C>G p.L9= | Silent (SNP) | VAF 68/797 reads (9%) | catalogued as COSV55946538; called by muse, mutect2
- NCR2 | c.531-15C>G | Intron (SNP) | VAF 45/391 reads (12%) | called by muse, varscan2
